CCDI case PBBRLT — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Palate.
https://portal.gdc.cancer.gov/cases/8584149b-da04-4863-91a2-b8967a5309b2

Demographics
Sex at birth: female; Race: asian; Vital status: Alive.

Diagnoses (1)
1. Mucoepidermoid carcinoma: ICD-O-3 morphology code: 8430/3; Tissue or organ of origin: Hard palate; Age at diagnosis: 7.0 years (2,556 days).

Biospecimens (2 samples)
- Sample 0DOLUP: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DOLV8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
